Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A3DH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A3DH-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3
adenocarcinoma, endometrioid, Nos 8380/3
Site: Endometrium c54.1
lw
10/21/11

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, right and left ovaries and fallopian tubes, hysterectomy, and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (2.8 x 2.0 x 1.4 cm). The tumor invades 0.2 cm into the myometrium (total wall thickness 1.8 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.

B. Lymph nodes, right pelvic, excision: Multiple (18) lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, excision: Multiple (20) lymph nodes are negative for tumor.

D. Lymph nodes, additional right and left, excision: Multiple (10) lymph nodes are negative for tumor.

E. Omentum, biopsy: Negative for tumor.

F. Gonadal vessels, left, excision: Negative for tumor.

G. Gonadal vessels, right, excision: Negative for tumor.

H. Lymph nodes, right para-aortic, excision: Multiple (14) lymph nodes are negative for tumor.

With available surgical material [AJCC pT1N0] (7th edition, 2010)

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 105.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 2.8 x 2.0 x 1.4 cm exophytic mass in the fundus of the endometrial cavity grossly invading 0.1 cm. The myometrial thickness is 1.8 cm. There are no uterine leiomyomas. There is a 2.5 x 1.1 x 0.9 cm right ovary with a smooth outer surface and a solid cut surface with a 6.9 x 0.5 cm right fallopian tube which has multiple paratubal cysts. There is a 3.3 x 1.9 x 0.9 cm left ovary with a smooth outer surface and a solid cut surface with a 7.4 x 0.6 cm left fallopian tube which has multiple paratubal cysts. Representative sections are submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 6.0 x 3.5 x 1.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 6.5 x 3.9 x 1.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes all submitted.

D. Received fresh labeled "additional left and right pelvic lymph nodes" is a 3.0 x 2.5 x 1.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes all submitted.

[page 2 of 2]
E. Received fresh labeled "omental biopsy" is a 6.8 x 5.7 x 0.8 cm portion of omentum. Grossly unremarkable. Representative sections are submitted.

F. Received fresh labeled "left gonadal vessels" is a 6.4 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel. Representative sections are submitted

G. Received fresh labeled "right gonadal vessels" is a 4.5 cm in length by 0.6 cm in diameter portion of unremarkable blood vessel. Representative sections are submitted.

H. Received fresh labeled "right para-aortic lymph nodes" is a 3.5 x 2.5 x 1.3 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

Source: NCI Genomic Data Commons file 66c0424b-eca9-42a4-94fa-8850b3a5158d (TCGA-D1-A3DH.C63CF985-CF78-42EE-A7A2-22083FED571D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).